Gene-level copy-number profile of tumor specimen TCGA-XE-AAO7-01A from TCGA case TCGA-XE-AAO7, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 22.0 years (8,040 days).
Specimen TCGA-XE-AAO7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b012f519-5ac4-4090-9e96-dfeb74944fea.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-XE-AAO7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,905 have no estimate.
https://portal.gdc.cancer.gov/files/12bdd305-6456-472c-a56b-a9caefbef0f0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 1,474; copy number 2: 17,560; copy number 3: 27,187; copy number 4: 11,585; copy number 5: 141; copy number 6: 69; copy number 8: 25; copy number 9: 103; copy number 10: 135; copy number 12: 49; copy number 14: 73; copy number 15: 174; copy number 16: 19; copy number 17: 39; copy number 18: 65.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr17:36,165,681–36,439,566, 14 genes (within-gene range 0–2): TBC1D3B, AC243829.1, CCL3L3, CCL4L2, AC243829.5, AC243829.3, AC243829.6, TBC1D3I, AC233699.1, Y_RNA, TBC1D3G, TBC1D3H, RNU6-1192P, TBC1D3F.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 671 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–34,249,958, 671 genes, copy number 8–18 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,474. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
